Gene-level copy-number profile of tumor specimen TCGA-CV-6942-01A from TCGA case TCGA-CV-6942, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 73.8 years (26,941 days).
Specimen TCGA-CV-6942-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.fe8ee317-11bd-4500-a793-0106d969e1ca.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-6942-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0312990e-c5bc-4676-850e-741256ecd4f5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 7,303; copy number 2: 48,107; copy number 3: 3,839; copy number 4: 201; copy number 5: 167; copy number 6: 2; copy number 7: 79; copy number 8: 71; copy number 9: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-6942-01A-21D-2010-01): tumor purity 0.44, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.
- chr11:20,574,186–20,659,285, 3 genes: HMGB1P40, AC090707.2, SLC6A5.
- chr11:20,670,425–20,671,297, 1 gene: AC090707.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 329 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:452,492–7,175,648, 120 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr11:29,668,886–29,669,628, 1 gene, copy number 7: HNRNPRP2.
- chr11:29,721,399–29,726,565, 2 genes, copy number 7: RN7SL240P, RPL7AP58.
- chr11:34,404,663–36,289,449, 36 genes, copy number 8: AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9.
- chr11:36,321,158–36,323,440, 1 gene, copy number 8: AC087277.1.
- chr11:38,498,995–38,646,384, 2 genes, copy number 6: AC021713.1, LINC02759.
- chr11:65,823,022–67,443,821, 102 genes, copy number 5 (broad region; genes not listed).
- chr11:76,349,956–78,582,156, 64 genes, copy number 5 (broad region; genes not listed).
- chr11:78,749,250–78,756,480, 1 gene, copy number 5: AP002768.1.

Autosomal genes at a single copy (total copy number 1): 7,059. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
